Surgical pathology report (de-identified scan), TCGA case TCGA-33-AASL, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Johns Hopkins, specimen TCGA-33-AASL-01A (Primary Tumor).

[page 1 of 5]
=====

INTERPRETATION AND DIAGNOSIS:

1. LUNG, RIGHT UPPER LOBE (LOBECTOMY): INFILTRATING, POORLY DIFFERENTIATED SQUAMOUS CELL CARCINOMA (7CM DIAMETER) OF LUNG. SURROUNDING LUNG SHOWS MICROABSCCESS FORMATION AND EMPHYSEMATOUS BULLAE. ONE LYMPH NODE AND SURGICAL MARGINS, NEGATIVE FOR TUMOR.
2. SOFT TISSUE R-11 (EXCISION): ONE (1) LYMPH NODE AND ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.
3. SOFT TISSUE, R-4 (EXCISION): ONE (1) LYMPH NODE AND ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.
4. SOFT TISSUE, STATION (EXCISION): ONE (1) LYMPH NODE AND ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.
5. SOFT TISSUE, R- 10 (EXCISION): ONE (1) LYMPH NODE AND ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.
6. SOFT TISSUE PARIETAL PLEURAL MARGIN (RESECTION): DENSE FIBROSIS WITH CHRONIC INFLAMMATION, NEGATIVE FOR TUMOR.

*Electronic signature

=====

Clinical History:
SQUAMOUS CELL CANCER.

GROSS DESCRIPTION

(Continued on next page.)

ICD O-3
Carcinoma, squamous cell NOS
8070/3
Site: R Lung, upper lobe
0.34.1
JH 5/28/14

[page 2 of 5]
SURGICAL
PATHOLOGY

PART #1: RIGHT UPPER LOBE
Resident Pathologist:

Dictated by

The specimen is received fresh , labeled with the patient's name [REDACTED] and designated as right upper lobe. It consists of a grossly recognizable lobe of lung, weighing 360 gm and measuring 15 x 11 x 6 cm. The outer surface of the lung is a dark purple-red color and it is of soft spongy consistency. There is a hard, raised nodule on the anti-hilar portion which measures approximately 7 cm in diameter. Cutting open the hard mass, reveals a hard spongy, yellow-white interior. The external pleural surface of the mass has been inked black. There are two stapled margins which are cut open and inked black. The tumor appears attached to the pleural surface, but there is no scarring or puckering of the pleura surface over the tumor. The superior surgical stapled margin is 5.5 cm in length and the inferior surgical stapled margin is 5 cm in length. The tumor is approximately 0.5 cm away from the superior surgical margin, and approximately 1 cm away from the inferior surgical margin. There are some grossly visible bullae on the apical posterior side of the outside of the lung. Approximately five percent (5%) of the specimen is submitted. Some of the pieces were submitted for further studies.

SUMMARY OF SECTIONS

1	-	A	-	1	(ONE-HALF OF HILAR LYMPH NODE)
1	-	B	-	1	(BRONCHIAL MARGIN)
1	-	C	-	1	(VASCULAR MARGIN)
2	-	D&E	-	1	EACH (SUPERIOR SURGICAL MARGIN)
1	-	F	-	1	(INFERIOR SURGICAL MARGIN)
1	-	G	-	1	(TUMOR TO PLEURA)
1	-	H	-	1	(BULLAE)
1	-	I	-	1	(NORMAL LUNG)
9	-	TOTAL-		9	

(Continued on next page.)

[page 3 of 5]
SURGICAL
PATHOLOGY

PART #2: R-11
Resident Pathologist:

Dictated by

The specimen is received fresh , labeled with the patient's name [REDACTED] and designated as R-11. It consists of one piece of brown-tan soft tissue, measuring 1.5 x 1.0 x 0.8 cm. Approximately seventy-five percent (75%) of the specimen is submitted. The other portion was submitted for further studies.

SUMMARY OF SECTIONS

1 - A - 1
1 -TOTAL- 1

PART #3: R-4
Resident Pathologist:

Dictated by

The specimen is received fresh , labeled with the patient's name [REDACTED] and designated as R-4. It consists of one piece of brown-tan soft tissue, measuring 1 x 0.5 x 0.2 cm. The specimen is submitted in its entirety.

SUMMARY OF SECTIONS

1 - A - 1
1 -TOTAL- 1

(Continued on next page.)

[page 4 of 5]
SURGICAL
PATHOLOGY

=====

PART #4: STATION 7
Resident Pathologist:

Dictated by

The specimen is received fresh , labeled with the patient's name [REDACTED] and designated as Station 7. It consists of one piece of brown-tan soft tissue, measuring 1 x 1 x 0.5 cm. Approximately seventy-five percent (75%) of the specimen is submitted. Other pieces were submitted for further studies.

SUMMARY OF SECTIONS

1 - A - 1
1 -TOTAL- 1

PART #5: R 10
Resident Pathologist:

Dictated by

The specimen is received fresh , labeled with the patient's name [REDACTED] and designated as R-10. It consists of one piece of brown-tan soft tissue, measuring 2 x 1.5 x 0.8 cm. Approximately seventy-five percent (75%) of the specimen is submitted. The rest is submitted for further studies.

SUMMARY OF SECTIONS

1 - A - 1
1 -TOTAL- 1

(Continued on next page.)

[page 5 of 5]
SURGICAL
PATHOLOGY

PART #6: PARIETAL PLEURAL MARGIN

Resident Pathologist:

Dictated by

The specimen is received fresh , labeled with the patient's name [REDACTED] and designated as parietal pleura margin. It consists of a soft thin tissue, weighing 6.48 gm and measuring 9 x 2 x 0.4 cm. The specimen is thicker on one end and almost flat on the other. Serial sections were made, revealing white clear fibrous interior with a small harder yellow nodular-like part, measuring about 0.5 cm wide and 0.3 cm tall. The entire specimen is submitted.

SUMMARY OF SECTIONS

4 - A-D - M EACH
4 - TOTAL - M

Other Surgical Pathology Specimens known to the computer: [REDACTED]

(End of Report)

printed

Source: NCI Genomic Data Commons file 7dc4837d-b707-4a31-a86f-c5309d32cc9b (TCGA-33-AASL.BA440A37-33C3-4154-9015-2EA006E50E0C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).